Gene-level copy-number profile of tumor specimen TCGA-KQ-A41S-01A from TCGA case TCGA-KQ-A41S, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 87.7 years (32,041 days).
Specimen TCGA-KQ-A41S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.7a9d216b-d46a-4fe6-8df3-a265f20fa1bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KQ-A41S-10C (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1936f423-204a-476a-80db-762978ee6ae3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,444; copy number 3: 7,239; copy number 4: 21,869; copy number 5: 9,584; copy number 6: 10,869; copy number 7: 3,801; copy number 8: 3,974; copy number 10: 216; copy number 11: 114; copy number 14: 253; copy number 15: 457.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KQ-A41S-01A-12D-A338-01): tumor purity 0.41, ploidy 5.01, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,040 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 14–15 (broad region; genes not listed).
- chr6:44,387,706–44,450,425, 2 genes, copy number 11: CDC5L, MIR4642.
- chr18:47,390–14,132,490, 328 genes, copy number 10–11 (within-gene range 8–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
